CMI case ASCProject_0006 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/0ef6799f-f3cc-4a87-9dce-ca192f5f2221

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 29.9 years (10,916 days).

Biospecimens (3 samples)
- Sample ASCProject_0006_BLOOD_Normal: Sample type: DNA; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood.
- Sample ASCProject_0006_BLOOD_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Blood.
- Sample ASCProject_0006_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: FFPE.
